Somatic mutation profile of tumor specimen BA2254D (aliquot aq-BA2254D) from BEATAML1.0 case 2540, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.7 years (20,705 days).
Specimen BA2254D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62f7f56d-7000-4c93-82fc-4e65581c0716.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2810D (Solid Tissue Normal), aliquot aq-BA2810D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d689ce15-9546-4162-bca6-a35c4c6d8bc7

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 180/415 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 150/202 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- VANGL2 | c.939A>G p.E313= | Splice Region (SNP) | VAF 86/177 reads (49%) | called by mutect2, varscan2
- ZNF292 | c.5128C>G p.L1710V | Missense Mutation (SNP) | VAF 99/201 reads (49%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ZNF560 | c.1307A>T p.H436L | Missense Mutation (SNP) | VAF 89/176 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MIP | c.606+24A>G | Intron (SNP) | VAF 59/160 reads (37%) | called by muse, mutect2, varscan2
